Somatic mutation profile of tumor specimen ALCH-B5VF-TTP1-A (aliquot ALCH-B5VF-TTP1-A-3-0-D-A87U-36) from ALCHEMIST case ALCH-B5VF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Age at diagnosis: 71.4 years (26,070 days).
Specimen ALCH-B5VF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 449ad0aa-5ea2-4742-9b71-d899bab20cc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B5VF-NB1-A (Blood Derived Normal), aliquot ALCH-B5VF-NB1-A-1-0-D-A87U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7665080d-b4f2-45e8-b02e-308c4581d560

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, Intron 4, 3'UTR 2, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP3 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51088415; called by muse, mutect2, varscan2
- CAMK1D | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66609693; called by muse, mutect2
- GRM4 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); catalogued as rs780623697; called by muse, mutect2
- HIVEP1 | c.7940A>C p.K2647T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1365366756; called by muse, mutect2
- LRIT2 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV100928288; called by muse, mutect2, varscan2
- MGAT2 | c.1234_1237del p.T412Sfs*8 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as rs776720499; called by mutect2, pindel
- NSD2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100373627; called by muse, mutect2, varscan2
- PHKA1 | c.2729G>T p.G910V | Missense Mutation (SNP) | VAF 52/508 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs782722259, COSV100263155, COSV59801958; called by muse, mutect2, varscan2
- PRKX | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232822524; called by muse, mutect2, varscan2
- TBC1D13 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56353787; called by muse, mutect2, varscan2
- TSPAN19 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs1430919434, COSV70814521; called by muse, mutect2, varscan2
- B3GALT2 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 35/369 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- C1GALT1C1 | c.580A>G p.M194V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPC2 | c.737C>A p.T246K | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2
- IGLV3-12 | c.42C>A p.C14* | Nonsense Mutation (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- INTS4 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- IPMK | c.50dup p.E18Rfs*13 | Frame Shift Ins (INS) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- LRP1 | c.10192G>A p.D3398N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- MRPS23 | c.569C>G p.P190R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); called by muse, mutect2
- MUC17 | c.11468C>T p.P3823L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); called by muse, mutect2
- PDIK1L | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLXNC1 | c.2572G>T p.E858* | Nonsense Mutation (SNP) | VAF 17/172 reads (10%) | called by muse, mutect2, varscan2
- RYR2 | c.4910G>T p.R1637I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- STN1 | c.813A>G p.I271M | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); called by muse, mutect2
- TRIML1 | c.1089C>A p.S363R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.425); called by muse, varscan2
- TXNDC15 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.133); called by muse, mutect2
- C11orf53 | c.723G>A p.T241= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs141303852; called by muse, mutect2, varscan2
- CENPQ | c.30A>G p.K10= | Silent (SNP) | VAF 47/464 reads (10%) | called by muse, mutect2
- FBXO10 | c.2424C>T p.I808= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, varscan2
- GOLGA3 | c.2484G>A p.Q828= | Silent (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- TTC37 | c.741A>G p.L247= | Silent (SNP) | VAF 36/442 reads (8%) | called by muse, mutect2
- AFP | c.*53T>G | 3'UTR (SNP) | VAF 68/298 reads (23%) | called by muse, mutect2, varscan2
- DST | c.414+6611C>A | Intron (SNP) | VAF 79/587 reads (13%) | called by muse, mutect2, varscan2
- ELP4 | c.*13A>T | 3'UTR (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2
- MUC19 | n.5194C>T | RNA (SNP) | VAF 24/316 reads (8%) | called by muse, mutect2
- NDST4 | c.2115+3103C>T | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- PBRM1 | c.2567+34A>G | Intron (SNP) | VAF 5/33 reads (15%) | catalogued as rs779429634; called by muse, varscan2
- USH1C | c.1284+5464G>A | Intron (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
